Somatic mutation profile of tumor specimen ALCH-AEJZ-TTP1-A (aliquot ALCH-AEJZ-TTP1-A-1-0-D-A596-36) from ALCHEMIST case ALCH-AEJZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Non-small cell carcinoma; Age at diagnosis: 74.3 years (27,152 days).
Specimen ALCH-AEJZ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 199d28a2-ac26-4dea-9da2-156db0b17df6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEJZ-NB1-A (Blood Derived Normal), aliquot ALCH-AEJZ-NB1-A-1-0-D-A596-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6a9250c-33c6-40db-af2b-096ddddad027

The open-access MAF lists 1,107 somatic variants for this specimen: 780 protein-altering or splice-affecting, 194 silent, 133 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 662, Silent 194, Intron 67, Nonsense Mutation 57, Frame Shift Del 26, RNA 22, 3'UTR 20, Splice Site 17, 5'UTR 13, Splice Region 10, 3'Flank 8, Frame Shift Ins 6.

Variants (750 of 1,107; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.4243G>T p.E1415* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as rs397507327, CM118868, COSV66447909; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GPR179 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 58/303 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776996552; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3727C>T p.R1243W | Missense Mutation (SNP) | VAF 116/422 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60786131, COSV60797427; called by muse, mutect2, varscan2
- TP53 | c.695T>A p.I232N | Missense Mutation (SNP) | VAF 85/406 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as CM103212, COSV52661257, COSV52760307, COSV52829354; called by muse, mutect2, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 69/307 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.10291G>T p.V3431L | Missense Mutation (SNP) | VAF 36/354 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV71288847; called by muse, mutect2, varscan2
- ABI1 | c.763A>T p.S255C | Missense Mutation (SNP) | VAF 90/454 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as rs771562690; called by muse, mutect2, varscan2
- ACACB | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 115/375 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779621331, COSV58129585; called by muse, mutect2, varscan2
- ADAM18 | c.493C>A p.Q165K | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV55844807; called by muse, mutect2, varscan2
- ADAMTS17 | c.2083G>T p.D695Y | Missense Mutation (SNP) | VAF 99/414 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99171574; called by muse, mutect2, varscan2
- ADAMTS19 | c.1654C>A p.P552T | Missense Mutation (SNP) | VAF 102/445 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50821051; called by muse, mutect2, varscan2
- ADGRB3 | c.981C>A p.S327R | Missense Mutation (SNP) | VAF 41/305 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV65386694, COSV65395370; called by muse, mutect2, varscan2
- ADGRL3 | c.4338C>A p.Y1446* (on ENST00000506720 / NM_001322402.2; = p.Y1335* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 82/324 reads (25%) | catalogued as COSV101541163; called by muse, mutect2, varscan2
- AP2A1 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV62817197, COSV62820811; called by muse, mutect2
- AQP9 | c.662T>A p.L221Q | Missense Mutation (SNP) | VAF 77/337 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54968617; called by muse, mutect2, varscan2
- ARHGAP36 | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV52265981, COSV52270515; called by muse, mutect2, varscan2
- ARHGEF15 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.994); catalogued as COSV62725845; called by muse, mutect2, varscan2
- ARHGEF17 | c.2395G>A p.V799I | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.344); catalogued as rs758488742; called by muse, mutect2, varscan2
- ATP10D | c.2341G>T p.V781F | Missense Mutation (SNP) | VAF 53/368 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99905719; called by muse, mutect2, varscan2
- BCAN | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773481602; called by muse, mutect2, varscan2
- C4orf54 | c.3825G>A p.W1275* | Nonsense Mutation (SNP) | VAF 49/167 reads (29%) | catalogued as rs1162861404; called by muse, mutect2, varscan2
- CAPZA1 | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as rs764250947, COSV54145279; called by muse, mutect2, varscan2
- CCDC178 | c.1340C>A p.T447K | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.037); catalogued as rs772008637; called by muse, mutect2, varscan2
- CCDC197 | c.699del p.F233Lfs*? | Frame Shift Del (DEL) | VAF 58/260 reads (22%) | catalogued as COSV58939301; called by mutect2, varscan2
- CCR3 | c.983T>A p.I328N | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.172); catalogued as rs1237177318; called by muse, mutect2, varscan2
- CD163 | c.2542G>A p.G848S | Missense Mutation (SNP) | VAF 92/549 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63129741; called by muse, mutect2, varscan2
- CD34 | c.355A>C p.T119P | Missense Mutation (SNP) | VAF 209/838 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs779002641; called by muse, mutect2, varscan2
- CDH11 | c.1867A>C p.I623L | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.78); catalogued as rs775862772; called by muse, mutect2, varscan2
- CDH12 | c.1321A>T p.I441F | Missense Mutation (SNP) | VAF 39/346 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV66447232; called by muse, mutect2, varscan2
- CEP290 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 49/256 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as rs547665147; called by muse, mutect2, varscan2
- CFH | c.1225G>T p.G409C | Missense Mutation (SNP) | VAF 103/505 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100661687; called by muse, mutect2, varscan2
- CLCN4 | c.1756G>T p.V586L | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV66465149; called by muse, mutect2, varscan2
- CLUH | c.2911G>T p.V971F (on ENST00000435359; = p.V1010F on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV101425960; called by muse, mutect2, varscan2
- CNOT4 | c.1067G>T p.S356I (on ENST00000315544 / NM_001190848.1; = p.S353I on NM_013316.4) | Missense Mutation (SNP) | VAF 202/406 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs551935402; called by muse, mutect2, varscan2
- CNTNAP4 | c.2687C>A p.T896K | Missense Mutation (SNP) | VAF 36/474 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV56668932; called by muse, mutect2
- COL16A1 | c.3488C>T p.P1163L | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs751545107; called by muse, mutect2, varscan2
- COL22A1 | c.3977C>T p.P1326L | Missense Mutation (SNP) | VAF 39/474 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.24); catalogued as rs202129460; called by muse, mutect2
- COL3A1 | c.2131G>T p.G711C | Missense Mutation (SNP) | VAF 607/1183 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM026026, COSV100482809; called by muse, mutect2, varscan2
- CREM | c.500G>T p.G167V (on ENST00000429130; = p.G118V on NM_001881.3) | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59766453; called by muse, mutect2, varscan2
- CSH1 | c.519C>A p.D173E | Missense Mutation (SNP) | VAF 186/966 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.946); catalogued as COSV60242064; called by muse, varscan2
- CSMD1 | c.4768C>A p.Q1590K (on ENST00000520002; = p.Q1589K on NM_033225.6) | Missense Mutation (SNP) | VAF 22/380 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as rs1370137894, COSV59328518; called by muse, mutect2
- CSMD3 | c.9890C>A p.P3297H (on ENST00000297405 / NM_001363185.1; = p.P3128H on NM_052900.3) | Missense Mutation (SNP) | VAF 36/417 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52286476; called by muse, mutect2
- CSMD3 | c.8668G>C p.G2890R (on ENST00000297405 / NM_001363185.1; = p.G2721R on NM_052900.3) | Missense Mutation (SNP) | VAF 59/394 reads (15%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.989); catalogued as COSV52206023; called by muse, mutect2, varscan2
- CTAGE1 | c.719G>T p.R240L | Missense Mutation (SNP) | VAF 92/393 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.168); catalogued as rs762042711; called by muse, mutect2, varscan2
- CTAGE1 | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 130/773 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as rs376319377; called by muse, mutect2, varscan2
- CTNNA3 | c.626C>A p.A209D | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1438389311, COSV65606256; called by muse, mutect2, varscan2
- CTNND2 | c.2594G>T p.G865V | Missense Mutation (SNP) | VAF 99/303 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100481002; called by muse, mutect2, varscan2
- CYLC2 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as COSV66336461, COSV66339631; called by muse, mutect2, varscan2
- CYP27B1 | c.1295G>C p.R432P | Missense Mutation (SNP) | VAF 87/241 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56984418; called by muse, mutect2, varscan2
- DCAF12L1 | c.554T>A p.L185Q | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs986958118; called by muse, mutect2
- DCAF4L2 | c.297C>A p.Y99* | Nonsense Mutation (SNP) | VAF 16/233 reads (7%) | catalogued as COSV60477865; called by muse, mutect2
- DCHS1 | c.8971C>T p.R2991W | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs745798498, COSV100197387; called by muse, mutect2, varscan2
- DCHS2 | c.104G>C p.R35P | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.663); catalogued as rs540887773; called by muse, mutect2, varscan2
- DDI2 | c.934A>G p.I312V | Missense Mutation (SNP) | VAF 42/363 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.025); catalogued as COSV60781194; called by muse, mutect2, varscan2
- DDX39B | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 44/680 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as rs1157085249; called by muse, mutect2
- DENND3 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.079); catalogued as COSV52800770; called by muse, mutect2, varscan2
- DENND4A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs755658461, COSV71266869; called by muse, varscan2
- DGKB | c.1270G>T p.D424Y | Missense Mutation (SNP) | VAF 165/537 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as COSV51806588; called by muse, mutect2, varscan2
- DHRS13 | c.521G>A p.C174Y | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.089); catalogued as COSV60457127; called by muse, mutect2, varscan2
- DIAPH2 | c.844A>G p.I282V | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.124); catalogued as COSV61287309; called by muse, mutect2, varscan2
- DNAH11 | c.1429A>G p.I477V | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs1009606912; called by muse, mutect2, varscan2
- DNAH8 | c.6536C>A p.T2179K | Missense Mutation (SNP) | VAF 181/593 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59466746; called by muse, mutect2, varscan2
- DNAH9 | c.10765G>T p.A3589S | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.111); catalogued as rs141804167, COSV52354755; called by muse, mutect2, varscan2
- DNMT3A | c.1319G>A p.W440* | Nonsense Mutation (SNP) | VAF 12/90 reads (13%) | catalogued as rs773260349; called by muse, mutect2, varscan2
- DNMT3A | c.760del p.A254Hfs*62 | Frame Shift Del (DEL) | VAF 47/128 reads (37%) | catalogued as COSV53046000, COSV53053569; called by mutect2, pindel, varscan2
- DPEP1 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as rs771235291; called by muse, mutect2, varscan2
- DPPA2 | c.241C>G p.P81A | Missense Mutation (SNP) | VAF 137/510 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV101524766; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2445C>A p.N815K | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV62568198; called by muse, mutect2, varscan2
- EPHA3 | c.142C>A p.P48T | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60698692, COSV60722017; called by muse, mutect2, varscan2
- EPS8L3 | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV62609925; called by muse, mutect2, varscan2
- EXOC6B | c.2090A>G p.Q697R | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as rs773905467; called by muse, mutect2, varscan2
- EXTL3 | c.1913C>G p.P638R | Missense Mutation (SNP) | VAF 50/258 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99593851; called by muse, mutect2, varscan2
- FAM133A | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV59076342; called by muse, mutect2, varscan2
- FAM135B | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs762478827, COSV52715939; called by muse, varscan2
- FAM71F2 | c.501G>T p.W167C | Missense Mutation (SNP) | VAF 414/894 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101100649; called by muse, mutect2, varscan2
- FBN1 | c.6337T>A p.Y2113N | Missense Mutation (SNP) | VAF 88/696 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.361); catalogued as CD098550; called by muse, mutect2
- FBN1 | c.6335C>A p.P2112H | Missense Mutation (SNP) | VAF 88/690 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV57308845; called by muse, mutect2
- FBN1 | c.1408G>T p.G470W | Missense Mutation (SNP) | VAF 92/564 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100354180; called by muse, mutect2, varscan2
- FBXO33 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as rs1475040250; called by muse, mutect2, varscan2
- FGF3 | c.463G>T p.V155L | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.928); catalogued as rs143483033, COSV61925214; called by muse, mutect2
- FLNC | c.2845G>A p.D949N | Missense Mutation (SNP) | VAF 310/600 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs761905908; called by muse, mutect2, varscan2
- FLT3 | c.2917C>G p.R973G | Missense Mutation (SNP) | VAF 37/475 reads (8%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as COSV54051999; called by muse, mutect2
- FMN2 | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 77/409 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.006); catalogued as rs748393494, COSV60431235; called by muse, mutect2, varscan2
- FRAS1 | c.7542G>T p.L2514F | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53601022; called by muse, mutect2, varscan2
- FSIP2 | c.2507C>T p.S836F | Missense Mutation (SNP) | VAF 113/228 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); catalogued as COSV100556139, COSV58082789; called by muse, mutect2, varscan2
- GABRA2 | c.1210C>G p.P404A | Missense Mutation (SNP) | VAF 96/563 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV62913637; called by muse, mutect2, varscan2
- GABRG1 | c.804A>T p.R268S | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV99778112; called by muse, mutect2, varscan2
- GAK | c.3393G>T p.W1131C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV100033571, COSV99041266; called by muse, mutect2, varscan2
- GFPT2 | c.2033C>A p.S678Y | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99517855; called by muse, mutect2
- GFRA4 | c.755G>T p.G252V (on ENST00000319242 / NM_145762.3; = p.G222V on NM_022139.4) | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs374283828; called by muse, mutect2, varscan2
- GOLGA8M | c.969G>T p.Q323H | Missense Mutation (SNP) | VAF 60/1228 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as rs1028502079; called by muse, mutect2
- GPR149 | c.1382C>A p.S461Y | Missense Mutation (SNP) | VAF 67/352 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV67668010; called by muse, mutect2, varscan2
- GPR171 | c.876C>G p.F292L | Missense Mutation (SNP) | VAF 52/381 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99852396; called by muse, mutect2, varscan2
- GPT | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 25/205 reads (12%) | catalogued as COSV52955068; called by muse, mutect2, varscan2
- GRAMD4 | c.958C>G p.L320V | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs369736360; called by muse, mutect2, varscan2
- GRIK2 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 78/317 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.792); catalogued as rs760579947, COSV59720927, COSV59731740; called by muse, mutect2, varscan2
- GRIP1 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 61/327 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs545072949; called by muse, mutect2, varscan2
- GRM3 | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64469309; called by muse, mutect2, varscan2
- GYG2 | c.1060C>A p.Q354K | Missense Mutation (SNP) | VAF 121/303 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV58549001; called by muse, mutect2, varscan2
- HAUS5 | c.1585C>T p.R529W | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1355448204; called by muse, mutect2, varscan2
- HDAC7 | c.1130G>T p.R377L (on ENST00000427332; = p.R416L on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs757098292, COSV50387308; called by muse, mutect2, varscan2
- HDX | c.1439G>T p.C480F | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99947388; called by muse, mutect2, varscan2
- HELZ2 | c.3610T>A p.F1204I (on ENST00000467148 / NM_001037335.2; = p.F635I on NM_033405.3) | Missense Mutation (SNP) | VAF 74/141 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV64410462; called by muse, mutect2, varscan2
- HHIPL1 | c.1697G>C p.R566P | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.264); catalogued as COSV100415055; called by muse, mutect2
- HSP90B1 | c.1502C>A p.S501* | Nonsense Mutation (SNP) | VAF 209/805 reads (26%) | catalogued as COSV55358665; called by muse, mutect2, varscan2
- HYDIN | c.13925G>T p.R4642L | Missense Mutation (SNP) | VAF 52/544 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765529216, COSV66639404; called by muse, mutect2
- HYDIN | c.416C>A p.S139* | Nonsense Mutation (SNP) | VAF 30/356 reads (8%) | catalogued as COSV55482951; called by muse, mutect2
- IGHV3-43 | c.79G>T p.G27W | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs560463151; called by muse, mutect2, varscan2
- IGKV1D-43 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 30/734 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as rs1200199111; called by muse, mutect2
- IGKV5-2 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); catalogued as rs1160244425; called by muse, mutect2
- ITGA5 | c.2346del p.R783Gfs*12 | Frame Shift Del (DEL) | VAF 38/168 reads (23%) | catalogued as COSV53218044; called by mutect2, pindel, varscan2
- ITGA8 | c.1056C>G p.S352R | Missense Mutation (SNP) | VAF 64/427 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100959390; called by muse, mutect2, varscan2
- JARID2 | c.2884G>A p.D962N | Missense Mutation (SNP) | VAF 61/275 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.346); catalogued as COSV59192387; called by muse, mutect2, varscan2
- KATNIP | c.3991G>T p.V1331F | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs752472912; called by muse, mutect2, varscan2
- KATNIP | c.4280G>T p.R1427L | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV55177210; called by muse, mutect2, varscan2
- KCNG4 | c.932C>G p.A311G | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.697); catalogued as COSV57583317; called by muse, mutect2, varscan2
- KDM4C | c.2500G>T p.A834S | Missense Mutation (SNP) | VAF 140/379 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs752425318; called by muse, varscan2
- KEAP1 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 46/190 reads (24%) | catalogued as COSV50661099; called by muse, mutect2, varscan2
- KIAA1217 | c.2339G>T p.R780L | Missense Mutation (SNP) | VAF 60/213 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100287010, COSV56819469; called by muse, mutect2, varscan2
- KIAA1671 | c.4368G>T p.W1456C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs1281036272; called by muse, mutect2, varscan2
- KIF22 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 126/528 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV50714634, COSV99361409; called by muse, mutect2, varscan2
- KIF5C | c.1189C>A p.P397T | Missense Mutation (SNP) | VAF 88/278 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV68482268; called by muse, mutect2, varscan2
- KISS1R | c.140T>A p.L47H | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1173327814; called by muse, mutect2, varscan2
- KLHDC9 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as rs774703980; called by muse, mutect2, varscan2
- KLHL1 | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 29/138 reads (21%) | catalogued as COSV100916836; called by muse, mutect2, varscan2
- KLHL4 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 162/366 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.556); catalogued as COSV100909141; called by muse, mutect2, varscan2
- KLHL4 | c.1180C>G p.L394V | Missense Mutation (SNP) | VAF 74/184 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as COSV64139767; called by muse, mutect2, varscan2
- KMT2C | c.2770-1G>T p.X924_splice | Splice Site (SNP) | VAF 14/129 reads (11%) | catalogued as COSV100074974; called by muse, mutect2, varscan2
- KMT2C | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 46/644 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs375186454; called by muse, mutect2
- KRT35 | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs770754537; called by muse, mutect2, varscan2
- LAMA1 | c.6721G>T p.D2241Y | Missense Mutation (SNP) | VAF 205/882 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV67544114; called by muse, mutect2, varscan2
- LHCGR | c.347C>A p.P116H | Missense Mutation (SNP) | VAF 246/732 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.669); catalogued as COSV54302071; called by muse, varscan2
- LIG1 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.716); catalogued as rs12981963, COSV54393231; called by muse, mutect2, varscan2
- LITAF | c.284G>A p.C95Y | Missense Mutation (SNP) | VAF 92/363 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as rs927004977; called by muse, mutect2, varscan2
- LRFN5 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 87/326 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.525); catalogued as COSV104402277; called by muse, mutect2, varscan2
- LRRC55 | c.689C>A p.P230H | Missense Mutation (SNP) | VAF 38/286 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73006538; called by muse, mutect2, varscan2
- LRRC7 | c.2347G>T p.A783S (on ENST00000651989 / NM_001370785.2; = p.A750S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs763412623; called by muse, mutect2, varscan2
- LRRC7 | c.3010G>C p.E1004Q (on ENST00000651989 / NM_001370785.2; = p.E971Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/460 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.345); catalogued as COSV50430525; called by muse, mutect2
- LRRK1 | c.4633G>T p.G1545C | Missense Mutation (SNP) | VAF 131/432 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as rs1373624280; called by muse, mutect2, varscan2
- LRRK2 | c.5815G>T p.G1939W | Missense Mutation (SNP) | VAF 90/553 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54144421; called by muse, mutect2, varscan2
- MAG | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1389823030; called by muse, mutect2, varscan2
- MAGEB6B | c.70G>T p.G24C | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.162); catalogued as rs745667920; called by muse, mutect2, varscan2
- MAN2C1 | c.839G>T p.W280L | Missense Mutation (SNP) | VAF 96/235 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as COSV99146026; called by muse, mutect2, varscan2
- MAPKBP1 | c.2260G>T p.G754C (on ENST00000456763 / NM_001128608.2; = p.G748C on NM_014994.3) | Missense Mutation (SNP) | VAF 70/289 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV52968012; called by muse, mutect2, varscan2
- MDGA2 | c.1825C>A p.P609T (on ENST00000399232 / NM_001113498.2; = p.P311T on NM_182830.4) | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV62115359; called by muse, mutect2
- MEI1 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 96/474 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs529584550; called by muse, mutect2, varscan2
- MOXD1 | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV60942482; called by muse, mutect2, varscan2
- MS4A12 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 47/380 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.437); catalogued as COSV50015126, COSV99189464; called by muse, mutect2, varscan2
- MS4A14 | c.425C>A p.P142Q | Missense Mutation (SNP) | VAF 94/467 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV55733133; called by muse, mutect2, varscan2
- MS4A18 | c.592G>T p.V198L (on ENST00000398983; = p.V200L on NM_001354471.1) | Missense Mutation (SNP) | VAF 88/311 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV67517807; called by muse, varscan2
- MYH15 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 56/237 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781378758, COSV56310663; called by muse, mutect2, varscan2
- MYH7 | c.827A>G p.Q276R | Missense Mutation (SNP) | VAF 67/607 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as rs1415025206; called by muse, mutect2, varscan2
- NAV3 | c.4874C>G p.S1625C | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV57091397; called by muse, mutect2, varscan2
- NDST4 | c.521G>T p.S174I | Missense Mutation (SNP) | VAF 72/244 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.152); catalogued as rs1257179067; called by muse, mutect2, varscan2
- NLRP12 | c.2276G>T p.C759F | Missense Mutation (SNP) | VAF 106/432 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs187043374; called by muse, mutect2, varscan2
- NLRP12 | c.2275T>C p.C759R | Missense Mutation (SNP) | VAF 106/433 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60747748; called by muse, mutect2, varscan2
- NOMO3 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 140/637 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as COSV53769849; called by muse, mutect2, varscan2
- NPAP1 | c.709C>G p.P237A | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.307); catalogued as COSV61506238, COSV61508049; called by muse, mutect2, varscan2
- NTRK1 | c.430G>C p.V144L | Missense Mutation (SNP) | VAF 74/328 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV100693764; called by muse, mutect2, varscan2
- NTRK3 | c.2494C>A p.P832T (on ENST00000360948 / NM_001012338.2; = p.P818T on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 144/570 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62299474, COSV62302752, COSV62313048; called by muse, mutect2, varscan2
- OR10J3 | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as rs376717490; called by muse, mutect2, varscan2
- OR10P1 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 80/264 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100548210; called by muse, mutect2, varscan2
- OR1F1 | c.476A>T p.H159L | Missense Mutation (SNP) | VAF 50/300 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV58962467; called by muse, mutect2, varscan2
- OR2G2 | c.488C>A p.S163Y | Missense Mutation (SNP) | VAF 44/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV60740540; called by muse, mutect2, varscan2
- OR2J2 | c.508T>G p.C170G | Missense Mutation (SNP) | VAF 34/386 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV65848249; called by muse, mutect2
- OR4A16 | c.372C>G p.I124M | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV59042527; called by muse, mutect2, varscan2
- OR4C13 | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 58/340 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs782343406; called by muse, mutect2, varscan2
- OR4C13 | c.751C>A p.P251T | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs782298071; called by muse, mutect2, varscan2
- OR4K1 | c.89T>A p.I30N | Missense Mutation (SNP) | VAF 37/422 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs1220971156; called by muse, mutect2
- OR51B6 | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 102/422 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.152); catalogued as COSV66514149; called by muse, mutect2, varscan2
- OR51E1 | c.759C>A p.F253L | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV67810979; called by muse, mutect2, varscan2
- OR56A3 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 65/307 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.11); catalogued as COSV100290322; called by muse, mutect2, varscan2
- OR5F1 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as rs1411497622, COSV99558577; called by muse, varscan2
- OR5L2 | c.766C>A p.L256I | Missense Mutation (SNP) | VAF 49/328 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.957); catalogued as COSV65723903; called by muse, mutect2, varscan2
- OR6X1 | c.281G>A p.C94Y | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs868858070; called by muse, mutect2, varscan2
- OR8H2 | c.600C>A p.F200L | Missense Mutation (SNP) | VAF 57/246 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as COSV57947606; called by muse, mutect2, varscan2
- OR8U1 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 44/301 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs747208338, COSV100163817; called by muse, mutect2, varscan2
- OTOGL | c.3085G>T p.E1029* (on ENST00000547103; = p.E1020* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as COSV72007498; called by muse, mutect2, varscan2
- PCDH10 | c.255C>G p.C85W | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52091066; called by muse, mutect2, varscan2
- PCDH15 | c.5149C>A p.P1717T | Missense Mutation (SNP) | VAF 109/420 reads (26%) | SIFT tolerated, low confidence (0.11); catalogued as COSV100903865; called by muse, mutect2, varscan2
- PCDH17 | c.1561A>T p.I521F | Missense Mutation (SNP) | VAF 49/264 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs368767010; called by muse, mutect2, varscan2
- PCDHGA12 | c.1270G>T p.A424S | Missense Mutation (SNP) | VAF 70/253 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV52770234; called by muse, mutect2, varscan2
- PCDHGB3 | c.2312del p.K771Rfs*78 | Frame Shift Del (DEL) | VAF 83/326 reads (25%) | catalogued as COSV53983910; called by mutect2, pindel, varscan2
- PDZRN4 | c.1501G>T p.E501* (on ENST00000402685 / NM_001164595.2; = p.E243* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 43/215 reads (20%) | catalogued as COSV54195652; called by muse, mutect2, varscan2
- PIP5K1B | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 85/217 reads (39%) | catalogued as COSV99600075; called by muse, mutect2, varscan2
- PODN | c.1264G>T p.V422L (on ENST00000395871; = p.V374L on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV100439811; called by muse, mutect2, varscan2
- POLE | c.595G>C p.G199R | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.214); catalogued as rs776540681; called by muse, mutect2, varscan2
- POU4F1 | c.1249G>C p.A417P | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101020550; called by muse, mutect2, varscan2
- PPP1R3A | c.2221C>T p.P741S | Missense Mutation (SNP) | VAF 64/663 reads (10%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.69); catalogued as COSV52883417; called by muse, mutect2
- PPP2R1A | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV59043910; called by muse, mutect2, varscan2
- PPWD1 | c.1256T>C p.I419T | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as rs750458713; called by muse, mutect2, varscan2
- PRDM9 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 119/729 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV57005795, COSV99691139; called by muse, mutect2, varscan2
- PRKCB | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 63/339 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1378724342; called by muse, mutect2, varscan2
- PROS1 | c.565G>T p.G189C | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM163575; called by muse, mutect2
- PRPH | c.1376G>T p.R459L | Missense Mutation (SNP) | VAF 110/384 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs982729267; called by muse, mutect2, varscan2
- PRTFDC1 | c.232G>T p.G78C | Missense Mutation (SNP) | VAF 95/557 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1467189077; called by muse, mutect2, varscan2
- PRX | c.3652G>A p.V1218M | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as rs1568702908; called by muse, mutect2, varscan2
- PTCHD3 | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV101438892, COSV71257113; called by muse, mutect2, varscan2
- PTPRK | c.1219G>T p.A407S | Missense Mutation (SNP) | VAF 74/236 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.935); catalogued as COSV63894174; called by muse, varscan2
- PXDNL | c.1856A>T p.Q619L | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.148); catalogued as rs1315249734; called by muse, mutect2, varscan2
- PYDC1 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 77/273 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs372347969; called by muse, mutect2, varscan2
- REG3G | c.519C>G p.F173L | Missense Mutation (SNP) | VAF 86/363 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.444); catalogued as COSV55449020; called by muse, mutect2, varscan2
- RERG | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 19/113 reads (17%) | catalogued as COSV57001333; called by muse, mutect2, varscan2
- RIT2 | c.636G>C p.K212N | Missense Mutation (SNP) | VAF 91/413 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.766); catalogued as COSV100452106; called by muse, mutect2
- SATB2 | c.1432G>A p.G478S | Missense Mutation (SNP) | VAF 425/855 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1043250716, COSV53487120; called by muse, mutect2, varscan2
- SCART1 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.747); catalogued as rs1383026465; called by muse, mutect2, varscan2
- SETD1A | c.4829G>T p.R1610L | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99352367; called by muse, mutect2, varscan2
- SETD1B | c.5556G>T p.M1852I | Missense Mutation (SNP) | VAF 71/259 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57352861; called by muse, mutect2, varscan2
- SGCB | c.863G>T p.C288F | Missense Mutation (SNP) | VAF 126/647 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1296865393; called by muse, mutect2, varscan2
- SGSM2 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs144724181; called by muse, mutect2, varscan2
- SHKBP1 | c.1024A>C p.N342H | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as COSV52544462; called by muse, mutect2, varscan2
- SHOX | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs761462186; called by muse, mutect2, varscan2
- SLC12A9 | c.526G>A p.G176S | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs752416781; called by muse, mutect2, varscan2
- SLC25A42 | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV100588225; called by muse, mutect2, varscan2
- SLC25A53 | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 84/172 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV62459202; called by muse, mutect2, varscan2
- SLC26A4 | c.532A>G p.T178A | Missense Mutation (SNP) | VAF 64/824 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.027); catalogued as CM1111816; called by muse, mutect2
- SLC39A4 | c.1543G>T p.V515L (on ENST00000301305 / NM_001374839.1; = p.V490L on NM_017767.3) | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as rs368695329; called by muse, mutect2
- SLC45A2 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 217/709 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs554113064, COSV56874201; called by muse, mutect2, varscan2
- SLC4A10 | c.1264G>T p.D422Y (on ENST00000446997 / NM_001354461.2; = p.D392Y on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55765431, COSV55781650; called by muse, mutect2, varscan2
- SLC4A10 | c.2607G>T p.M869I (on ENST00000446997 / NM_001354461.2; = p.M839I on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 204/494 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1263514300, COSV99765663; called by muse, mutect2, varscan2
- SLC5A8 | c.1121G>T p.R374I | Missense Mutation (SNP) | VAF 50/371 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as COSV101610622, COSV73310460; called by muse, mutect2, varscan2
- SLITRK1 | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as COSV65674164, COSV65674366; called by muse, mutect2, varscan2
- SMYD3 | c.484G>T p.A162S (on ENST00000490107 / NM_001375962.1; = p.A103S on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/646 reads (20%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.48); catalogued as rs1456376983; called by muse, mutect2, varscan2
- SNTG2 | c.1005G>C p.P335= | Splice Region (SNP) | VAF 22/248 reads (9%) | catalogued as rs562415359, COSV57990202; called by muse, mutect2
- SP140 | c.1333G>T p.E445* | Nonsense Mutation (SNP) | VAF 36/127 reads (28%) | catalogued as COSV100613604; called by muse, mutect2, varscan2
- SPANXN3 | c.109C>A p.P37T | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.461); catalogued as rs1417369691, COSV100980759; called by muse, mutect2, varscan2
- SRMS | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT tolerated (0.12); PolyPhen benign (0.137); catalogued as COSV99421826; called by muse, mutect2, varscan2
- STEAP4 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs567945524; called by muse, mutect2, varscan2
- STH | c.215C>A p.T72N | Missense Mutation (SNP) | VAF 86/301 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); catalogued as rs775654112; called by muse, mutect2, varscan2
- TAS1R2 | c.544C>A p.R182S | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs140292020; called by muse, mutect2
- TEX13C | c.2159C>A p.P720H | Missense Mutation (SNP) | VAF 146/416 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1254973856; called by muse, varscan2
- TGFBR3 | c.965C>A p.S322* | Nonsense Mutation (SNP) | VAF 46/190 reads (24%) | catalogued as COSV53024607; called by muse, mutect2, varscan2
- TLL1 | c.1378G>C p.A460P | Missense Mutation (SNP) | VAF 159/546 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs772090014; called by muse, mutect2, varscan2
- TLR6 | c.90C>A p.D30E | Missense Mutation (SNP) | VAF 66/413 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs185522984; called by muse, mutect2, varscan2
- TMEM71 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 41/417 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs551754127, COSV63457486, COSV63459280; called by muse, mutect2
- TNRC6A | c.3560G>T p.R1187M | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs1162343844; called by muse, mutect2, varscan2
- TNXB | c.5093C>T p.P1698L (on ENST00000647633; = p.P1451L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771493330; called by muse, mutect2, varscan2
- TPK1 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63639085; called by muse, mutect2
- TRIM48 | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 97/608 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV70161372; called by muse, mutect2, varscan2
- TSHZ3 | c.2550G>T p.M850I | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1461556859, COSV99078518; called by muse, mutect2, varscan2
- TTN | c.65743C>A p.P21915T (on ENST00000591111; = p.P14491T on NM_003319.4) | Missense Mutation (SNP) | VAF 86/153 reads (56%) | PolyPhen probably damaging (0.999); catalogued as rs750670403; called by muse, mutect2, varscan2
- UNC45A | c.1051G>T p.G351W | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746323012; called by muse, mutect2, varscan2
- UNC5C | c.1613C>G p.S538W | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.965); catalogued as COSV71662662; called by muse, mutect2
- UNC80 | c.5110G>T p.G1704W | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV55896644; called by muse, mutect2
- UNKL | c.1137C>A p.S379R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as COSV66769510; called by muse, mutect2, varscan2
- USH2A | c.6806G>A p.G2269D | Missense Mutation (SNP) | VAF 69/328 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100232247, COSV99048443; called by muse, mutect2, varscan2
- VIT | c.1924C>T p.H642Y (on ENST00000389975 / NM_001177969.1; = p.H657Y on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/416 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs201861599; called by muse, varscan2
- WNK1 | c.6041C>T p.P2014L (on ENST00000315939 / NM_018979.4; = p.P1766L on NM_014823.3) | Missense Mutation (SNP) | VAF 75/294 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs909810117; called by muse, mutect2, varscan2
- WNT4 | c.380C>A p.A127E | Missense Mutation (SNP) | VAF 150/530 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV99268706; called by muse, mutect2, varscan2
- WT1 | c.514C>A p.Q172K | Missense Mutation (SNP) | VAF 72/403 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as CD1212773; called by muse, mutect2, varscan2
- ZNF10 | c.532C>G p.Q178E | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs777253013, COSV50211701; called by muse, mutect2, varscan2
- ZNF142 | c.1835A>G p.H612R (on ENST00000411696 / NM_001379660.1; = p.H412R on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV101377009; called by muse, mutect2, varscan2
- ZNF267 | c.151del p.D51Tfs*2 | Frame Shift Del (DEL) | VAF 58/300 reads (19%) | catalogued as COSV100339819, COSV56254707; called by mutect2, pindel, varscan2
- ZNF415 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.525); catalogued as rs1215277711; called by muse, mutect2, varscan2
- ZNF430 | c.1596G>T p.K532N | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV99841901; called by muse, mutect2, varscan2
- ZNF521 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 62/289 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64123484, COSV64127386; called by muse, mutect2, varscan2
- ZNF524 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as rs1449763776, COSV55608135; called by muse, mutect2, varscan2
- ZRANB1 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 98/321 reads (31%) | catalogued as rs1476546944; called by muse, mutect2, varscan2
- A2ML1 | c.1433C>A p.P478Q | Missense Mutation (SNP) | VAF 39/248 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- AATK | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- ABCA9 | c.1804G>C p.V602L | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCD2 | c.1477G>T p.V493L | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ACACA | c.5846T>C p.L1949P | Missense Mutation (SNP) | VAF 184/701 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- ACSM2A | c.1591G>T p.V531L (on ENST00000219054; = p.V452L on NM_001308169.2) | Missense Mutation (SNP) | VAF 66/331 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, varscan2
- ACSM5 | c.1375dup p.M459Nfs*28 | Frame Shift Ins (INS) | VAF 64/453 reads (14%) | called by mutect2, pindel, varscan2
- ACSS3 | c.1628T>A p.M543K | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ACTL6A | c.514A>T p.S172C | Missense Mutation (SNP) | VAF 57/470 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTN2 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 163/677 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ACTRT1 | c.671T>A p.L224* | Nonsense Mutation (SNP) | VAF 71/182 reads (39%) | called by muse, mutect2, varscan2
- ADAM18 | c.1154C>A p.P385Q | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.284); called by muse, mutect2
- ADAM8 | c.1519G>C p.A507P | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- ADAMTS20 | c.2086G>T p.G696C | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS20 | c.962T>A p.V321D | Missense Mutation (SNP) | VAF 55/327 reads (17%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- ADGRD1 | c.118G>C p.A40P | Missense Mutation (SNP) | VAF 132/537 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ADGRG5 | c.65-2A>C p.X22_splice | Splice Site (SNP) | VAF 28/157 reads (18%) | called by muse, mutect2, varscan2
- ADH1B | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADRA1A | c.850T>C p.C284R | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- AFF3 | c.2171G>C p.G724A | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- AGRN | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AK9 | c.2408dup p.E804Gfs*3 | Frame Shift Ins (INS) | VAF 52/199 reads (26%) | called by mutect2, pindel, varscan2
- AL031777.2 | c.106C>A p.R36S | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- ALCAM | c.496G>T p.G166C | Missense Mutation (SNP) | VAF 21/281 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- ALDH1A2 | c.1309A>G p.R437G | Missense Mutation (SNP) | VAF 152/779 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ALMS1 | c.8108C>A p.P2703Q | Missense Mutation (SNP) | VAF 159/490 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ALX4 | c.35C>G p.S12W | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ANHX | c.488G>T p.S163I | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- ANKRD11 | c.5854C>T p.H1952Y | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- ANKRD24 | c.1078C>A p.L360M | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ANXA1 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- APBB1IP | c.1817C>A p.P606H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.893); called by muse, mutect2
- APOB | c.3161A>T p.N1054I | Missense Mutation (SNP) | VAF 73/638 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APOC1P1 | n.403G>A | Splice Region (SNP) | VAF 59/249 reads (24%) | called by muse, mutect2, varscan2
- AQP9 | c.226G>T p.G76C | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARFGEF2 | c.1682del p.K561Rfs*23 | Frame Shift Del (DEL) | VAF 216/930 reads (23%) | called by mutect2, pindel, varscan2
- ARFGEF2 | c.5287G>T p.G1763C | Missense Mutation (SNP) | VAF 264/514 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARHGEF38 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ARID1B | c.2542G>T p.G848W | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- ARID5B | c.23G>T p.W8L | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, varscan2
- ARL14 | c.368A>G p.N123S | Missense Mutation (SNP) | VAF 192/518 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARSB | c.897A>T p.T299= | Splice Region (SNP) | VAF 123/452 reads (27%) | called by muse, mutect2, varscan2
- ASTN1 | c.3232G>T p.V1078L | Missense Mutation (SNP) | VAF 82/254 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATF6 | c.1130G>T p.R377I | Missense Mutation (SNP) | VAF 48/326 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATG2A | c.2495G>T p.S832I | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- ATL3 | c.161A>T p.H54L | Missense Mutation (SNP) | VAF 164/804 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ATP8B1 | c.761A>C p.D254A | Missense Mutation (SNP) | VAF 109/480 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATR | c.3394G>C p.A1132P | Missense Mutation (SNP) | VAF 77/258 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATXN2L | c.2992G>T p.G998W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, varscan2
- AVEN | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- AXDND1 | c.938G>C p.R313P | Missense Mutation (SNP) | VAF 46/269 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- B4GALNT2 | c.1304T>A p.F435Y | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- BAHCC1 | c.1655C>G p.A552G | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BCL2L13 | c.592G>A p.G198S | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, varscan2
- BCO2 | c.1380A>T p.E460D | Missense Mutation (SNP) | VAF 130/433 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- BDP1 | c.4051G>A p.D1351N | Missense Mutation (SNP) | VAF 77/315 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BRINP3 | c.138G>T p.W46C | Missense Mutation (SNP) | VAF 113/606 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BTN2A1 | c.362G>C p.G121A | Missense Mutation (SNP) | VAF 68/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- C10orf67 | c.1492A>C p.S498R | Missense Mutation (SNP) | VAF 74/343 reads (22%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- C11orf24 | c.776A>T p.Q259L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.159); called by muse, mutect2
- C19orf18 | c.247A>C p.M83L | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- C1orf167 | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- C7orf26 | c.627G>A p.W209* | Nonsense Mutation (SNP) | VAF 30/180 reads (17%) | called by muse, mutect2
- CACNA1H | c.776G>T p.R259L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CACNA1I | c.4615G>C p.V1539L | Missense Mutation (SNP) | VAF 71/347 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- CACNA2D4 | c.1645-4G>T | Splice Region (SNP) | VAF 171/567 reads (30%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.266A>T p.Y89F | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CALN1 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.254); called by muse, mutect2
- CASP2 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 28/810 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.014); called by muse, mutect2
- CATSPERG | c.2771-5C>A | Splice Region (SNP) | VAF 42/157 reads (27%) | called by muse, mutect2, varscan2
- CCDC102B | c.437A>T p.Q146L | Missense Mutation (SNP) | VAF 110/524 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CCDC168 | c.4294C>A p.Q1432K | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.634); called by muse, varscan2
- CCDC175 | c.2104T>A p.Y702N | Missense Mutation (SNP) | VAF 33/275 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC197 | c.703del p.D235Tfs*? | Frame Shift Del (DEL) | VAF 53/319 reads (17%) | called by mutect2*, pindel, varscan2*
- CCDC87 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 78/251 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCKBR | c.724T>A p.S242T | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- CCR1 | c.641T>A p.V214D | Missense Mutation (SNP) | VAF 92/378 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CCR8 | c.176T>A p.V59D | Missense Mutation (SNP) | VAF 109/346 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CCSER1 | c.2006T>A p.F669Y | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CD163 | c.2372A>T p.K791I | Missense Mutation (SNP) | VAF 64/343 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- CD8A | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDC14C | c.1449G>T p.E483D (on ENST00000428251; = p.E376D on NM_152627.3) | Missense Mutation (SNP) | VAF 68/479 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CDC20B | c.576G>T p.W192C | Missense Mutation (SNP) | VAF 91/271 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- CDH10 | c.1004C>A p.P335Q | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CDH19 | c.203C>A p.S68Y | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CDH7 | c.333T>A p.D111E | Missense Mutation (SNP) | VAF 99/540 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CDH7 | c.626-2A>T p.X209_splice | Splice Site (SNP) | VAF 71/302 reads (24%) | called by muse, mutect2, varscan2
- CEP170 | c.2402G>T p.R801I | Missense Mutation (SNP) | VAF 98/583 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, varscan2
- CEP350 | c.2227del p.V743Ffs*21 | Frame Shift Del (DEL) | VAF 25/155 reads (16%) | called by mutect2, pindel, varscan2
- CFH | c.1549G>C p.A517P | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- CFTR | c.3436G>A p.A1146T | Missense Mutation (SNP) | VAF 54/536 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.943); called by muse, mutect2
- CHAC2 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CHD2 | c.4174C>A p.Q1392K | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.184); called by muse, varscan2
- CHD2 | c.4175A>G p.Q1392R | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CHD5 | c.632C>A p.A211E | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CHRNB2 | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHTOP | c.599dup p.R201Tfs*34 | Frame Shift Ins (INS) | VAF 69/440 reads (16%) | called by mutect2, pindel, varscan2
- CLEC4D | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 25/147 reads (17%) | called by muse, mutect2, varscan2
- CNDP1 | c.604G>C p.G202R | Missense Mutation (SNP) | VAF 122/689 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTNAP2 | c.209-1G>C p.X70_splice | Splice Site (SNP) | VAF 296/782 reads (38%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.3704G>T p.S1235I | Missense Mutation (SNP) | VAF 145/409 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- COL11A1 | c.5150C>A p.S1717* | Nonsense Mutation (SNP) | VAF 59/358 reads (16%) | called by muse, mutect2, varscan2
- COL11A1 | c.3778G>A p.A1260T | Missense Mutation (SNP) | VAF 72/374 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- COL11A1 | c.425A>T p.H142L | Missense Mutation (SNP) | VAF 63/587 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- COL12A1 | c.6453G>T p.K2151N | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- COLEC12 | c.1948G>T p.E650* | Nonsense Mutation (SNP) | VAF 24/144 reads (17%) | called by muse, mutect2
- CPNE1 | c.143A>C p.E48A (on ENST00000352393; = p.E53A on NM_003915.5) | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CREBBP | c.4120G>T p.G1374W | Missense Mutation (SNP) | VAF 84/434 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSMD3 | c.7173A>T p.Q2391H (on ENST00000297405 / NM_001363185.1; = p.Q2287H on NM_052900.3) | Missense Mutation (SNP) | VAF 36/643 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); called by muse, mutect2
- CSRNP3 | c.993G>C p.Q331H | Missense Mutation (SNP) | VAF 176/389 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSTL1 | c.356A>G p.Y119C | Missense Mutation (SNP) | VAF 98/460 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CXXC4 | c.680T>A p.M227K | Missense Mutation (SNP) | VAF 124/339 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CYP3A4 | c.1027G>T p.A343S | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.158); called by muse, mutect2
- CYP4F3 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 62/341 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCAF8L2 | c.1243C>A p.H415N | Missense Mutation (SNP) | VAF 107/254 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCC | c.1765A>C p.K589Q | Missense Mutation (SNP) | VAF 153/680 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- DCD | c.146del p.P49Qfs*3 | Frame Shift Del (DEL) | VAF 78/367 reads (21%) | called by mutect2, pindel, varscan2
- DDX60 | c.3714G>C p.Q1238H | Missense Mutation (SNP) | VAF 107/466 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- DHRS7C | c.421C>A p.L141M (on ENST00000330255 / NM_001220493.2; = p.L140M on NM_001105571.3) | Missense Mutation (SNP) | VAF 108/555 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMBT1 | c.4987T>C p.C1663R (on ENST00000338354 / NM_001377530.1; = p.C906R on NM_004406.3) | Missense Mutation (SNP) | VAF 17/312 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DMPK | c.211T>C p.F71L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DNAH8 | c.5081A>T p.Q1694L | Missense Mutation (SNP) | VAF 97/440 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DNAH9 | c.4382T>C p.L1461P | Missense Mutation (SNP) | VAF 69/334 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DNASE2B | c.772C>G p.R258G | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DOCK8 | c.1767G>T p.M589I | Missense Mutation (SNP) | VAF 256/624 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- DOCK9 | c.3221A>T p.H1074L (on ENST00000376460 / NM_001366676.2; = p.H1075L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- DOK6 | c.940C>G p.P314A | Missense Mutation (SNP) | VAF 65/350 reads (19%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPP6 | c.1253G>C p.C418S (on ENST00000377770 / NM_001364500.2; = p.C356S on NM_001936.5) | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DPP6 | c.1698C>A p.N566K (on ENST00000377770 / NM_001364500.2; = p.N504K on NM_001936.5) | Missense Mutation (SNP) | VAF 32/407 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2
- DPYSL5 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DSPP | c.2608A>G p.S870G | Missense Mutation (SNP) | VAF 287/1477 reads (19%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- DST | c.1037G>T p.R346L | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DTX3 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 37/365 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DUSP26 | c.214G>T p.G72* | Nonsense Mutation (SNP) | VAF 34/118 reads (29%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.13433G>T p.W4478L | Missense Mutation (SNP) | VAF 175/488 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DZANK1 | c.1282A>C p.K428Q (on ENST00000262547 / NM_001099407.1; = p.K235Q on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/603 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- EBF1 | c.1254C>A p.H418Q | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EFCAB12 | c.262A>T p.K88* | Nonsense Mutation (SNP) | VAF 18/163 reads (11%) | called by muse, mutect2, varscan2
- EIF3E | c.1304C>G p.P435R | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.149); called by muse, mutect2
- EIF3I | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 97/366 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ELAVL4 | c.657G>T p.Q219H | Missense Mutation (SNP) | VAF 58/490 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ELFN1 | c.2335C>G p.R779G | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELL | c.17A>T p.E6V | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ELOA | c.2245G>A p.A749T | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- EMILIN2 | c.2182G>T p.E728* | Nonsense Mutation (SNP) | VAF 82/308 reads (27%) | called by mutect2, varscan2
- EPDR1 | c.161T>C p.M54T | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHB4 | c.1269G>T p.E423D | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPOR | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERICH3 | c.1690G>T p.G564* | Nonsense Mutation (SNP) | VAF 32/117 reads (27%) | called by muse, mutect2, varscan2
- ERICH6 | c.1059G>T p.M353I | Missense Mutation (SNP) | VAF 138/466 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ERP27 | c.89C>A p.S30Y | Missense Mutation (SNP) | VAF 55/274 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- ESCO1 | c.1953+1G>T p.X651_splice | Splice Site (SNP) | VAF 63/332 reads (19%) | called by muse, mutect2, varscan2
- EXD3 | c.2199C>A p.D733E | Missense Mutation (SNP) | VAF 109/283 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- EYS | c.2137+1G>T p.X713_splice | Splice Site (SNP) | VAF 151/642 reads (24%) | called by muse, mutect2, varscan2
- EYS | c.193A>G p.K65E | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- FAM135B | c.2830G>T p.D944Y | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- FAM220A | c.125dup p.D42Efs*8 | Frame Shift Ins (INS) | VAF 166/593 reads (28%) | called by mutect2, pindel, varscan2
- FAM47C | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 115/248 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- FAM83H | c.1481G>T p.G494V | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- FANCE | c.1491G>T p.M497I | Missense Mutation (SNP) | VAF 169/537 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAT3 | c.13480G>C p.E4494Q | Missense Mutation (SNP) | VAF 156/555 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- FBXO7 | c.997del p.V333Sfs*7 | Frame Shift Del (DEL) | VAF 56/342 reads (16%) | called by mutect2, pindel, varscan2
- FCRL4 | c.1207G>C p.A403P | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FERMT1 | c.129G>T p.M43I | Missense Mutation (SNP) | VAF 89/539 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- FGF13 | c.20G>T p.S7I | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- FIGNL1 | c.1285G>T p.G429C | Missense Mutation (SNP) | VAF 87/258 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLG2 | c.4976G>A p.S1659N | Missense Mutation (SNP) | VAF 103/534 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FLNC | c.2723G>T p.G908V | Missense Mutation (SNP) | VAF 49/489 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- FLNC | c.6899G>T p.S2300I | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FNDC3A | c.3549C>G p.F1183L (on ENST00000492622 / NM_001079673.2; = p.F1127L on NM_014923.5) | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, varscan2
- GABRA2 | c.19A>T p.I7F | Missense Mutation (SNP) | VAF 87/455 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GAD2 | c.1130A>T p.H377L | Missense Mutation (SNP) | VAF 92/419 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- GAD2 | c.1510G>C p.V504L | Missense Mutation (SNP) | VAF 82/435 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- GAL3ST4 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GALNT17 | c.697G>T p.G233C | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- GALNT18 | c.1046A>T p.E349V | Missense Mutation (SNP) | VAF 67/274 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- GANAB | c.2246-1G>T p.X749_splice | Splice Site (SNP) | VAF 57/271 reads (21%) | called by muse, mutect2, varscan2
- GAPT | c.86G>T p.C29F | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GCN1 | c.1738G>T p.V580F | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GIT2 | c.1091del p.G364Vfs*10 (on ENST00000355312 / NM_057169.5; = p.G366Vfs*10 on NM_014776.5) | Frame Shift Del (DEL) | VAF 88/402 reads (22%) | called by mutect2, pindel, varscan2
- GK2 | c.792A>T p.L264F | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLS2 | c.709T>A p.Y237N | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- GOLGA6L22 | c.2383G>T p.E795* | Nonsense Mutation (SNP) | VAF 31/331 reads (9%) | called by muse, mutect2, varscan2
- GRHL3 | c.1779G>T p.R593S | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- GRID2 | c.2212G>T p.A738S | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- GRID2IP | c.1535T>C p.L512P | Missense Mutation (SNP) | VAF 83/204 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- GRIN3B | c.2163C>A p.S721R | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- GRP | c.333G>A p.W111* | Nonsense Mutation (SNP) | VAF 85/363 reads (23%) | called by muse, mutect2, varscan2
- GSDMC | c.91A>T p.T31S | Missense Mutation (SNP) | VAF 34/445 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.241); called by muse, mutect2
- GTF3C1 | c.4910C>G p.P1637R | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- HCN1 | c.1784-1G>C p.X595_splice | Splice Site (SNP) | VAF 82/639 reads (13%) | called by muse, mutect2, varscan2
- HCN1 | c.1535T>G p.M512R | Missense Mutation (SNP) | VAF 271/941 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HDAC9 | c.434A>T p.Q145L | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- HEG1 | c.1907A>T p.Y636F | Missense Mutation (SNP) | VAF 74/623 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HHLA1 | c.1294C>A p.P432T | Missense Mutation (SNP) | VAF 59/279 reads (21%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- HMMR | c.1682G>T p.R561I | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2
- HNRNPR | c.1104A>T p.E368D | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.255); called by muse, mutect2
- HNRNPUL2 | c.2074G>A p.D692N | Missense Mutation (SNP) | VAF 104/560 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- HSD11B2 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- HTR4 | c.200T>A p.L67Q | Missense Mutation (SNP) | VAF 231/783 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- IFT46 | c.45+2T>C p.X15_splice | Splice Site (SNP) | VAF 186/667 reads (28%) | called by muse, mutect2, varscan2
- IGKC | c.235T>C p.Y79H | Missense Mutation (SNP) | VAF 263/629 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IGKV1-5 | c.12G>T p.R4S | Missense Mutation (SNP) | VAF 176/626 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, varscan2
- IGKV2D-26 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 26/360 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.119); called by muse, mutect2
- IL12RB1 | c.302A>T p.D101V | Missense Mutation (SNP) | VAF 84/326 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IMPDH1 | c.325-4G>T | Splice Region (SNP) | VAF 26/331 reads (8%) | called by muse, mutect2
- IQSEC2 | c.994A>T p.K332* (on ENST00000642864 / NM_001111125.3; = p.K127* on NM_015075.2) | Nonsense Mutation (SNP) | VAF 112/234 reads (48%) | called by muse, mutect2, varscan2
- IRX6 | c.11del p.P4Hfs*98 | Frame Shift Del (DEL) | VAF 85/297 reads (29%) | called by mutect2, pindel, varscan2
- ITFG1 | c.1482A>T p.L494F | Missense Mutation (SNP) | VAF 38/406 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- ITPKC | c.2006dup p.L670Pfs*41 | Frame Shift Ins (INS) | VAF 52/237 reads (22%) | called by mutect2, pindel, varscan2
- ITPR2 | c.3631G>T p.G1211W | Missense Mutation (SNP) | VAF 35/468 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITPRIP | c.10G>T p.G4W | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- KCNK10 | c.1268T>A p.L423Q | Missense Mutation (SNP) | VAF 39/357 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- KCNK16 | c.136C>A p.Q46K | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNU1 | c.1202G>T p.R401M | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- KCTD8 | c.1086C>A p.S362R | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- KDM5A | c.3701A>G p.Q1234R | Missense Mutation (SNP) | VAF 169/668 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KIAA1549L | c.3793C>A p.Q1265K (on ENST00000321505; = p.Q1562K on NM_012194.3) | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIF2B | c.565C>G p.H189D | Missense Mutation (SNP) | VAF 57/424 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL1 | c.1844G>T p.S615I | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- KLHL38 | c.460A>T p.K154* | Nonsense Mutation (SNP) | VAF 34/311 reads (11%) | called by muse, mutect2, varscan2
- KRT75 | c.425T>A p.I142N | Missense Mutation (SNP) | VAF 81/322 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KRT76 | c.1828G>T p.G610* | Nonsense Mutation (SNP) | VAF 31/137 reads (23%) | called by muse, mutect2, varscan2
- KRT8 | c.1123C>T p.Q375* | Nonsense Mutation (SNP) | VAF 67/371 reads (18%) | called by muse, mutect2, varscan2
- KRTAP21-2 | c.124G>T p.G42C | Missense Mutation (SNP) | VAF 36/407 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- KY | c.1175T>A p.L392Q | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- LGSN | c.509G>T p.C170F | Missense Mutation (SNP) | VAF 38/286 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- LIFR | c.2821C>A p.P941T | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LIFR | c.2016G>T p.M672I | Missense Mutation (SNP) | VAF 230/796 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- LILRA4 | c.1492C>A p.Q498K | Missense Mutation (SNP) | VAF 57/272 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- LIPC | c.265G>T p.G89W | Missense Mutation (SNP) | VAF 74/654 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LONP2 | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); called by muse, mutect2
- LPXN | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 50/222 reads (23%) | called by muse, mutect2, varscan2
- LRGUK | c.1324T>A p.F442I | Missense Mutation (SNP) | VAF 238/481 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1B | c.13283G>T p.R4428M | Missense Mutation (SNP) | VAF 110/350 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LRRC69 | c.202G>T p.G68* | Nonsense Mutation (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
- LRRN3 | c.267C>A p.D89E | Missense Mutation (SNP) | VAF 115/398 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRTM4 | c.316C>A p.Q106K | Missense Mutation (SNP) | VAF 192/490 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- MAG | c.794G>A p.S265N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- MAGEB6 | c.805G>T p.G269C | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MAGEE1 | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEL2 | c.338C>G p.P113R | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MALRD1 | c.5206G>T p.G1736* | Nonsense Mutation (SNP) | VAF 44/216 reads (20%) | called by muse, mutect2, varscan2
- MAST1 | c.3644A>G p.Q1215R | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- MBD3L5 | c.209A>T p.N70I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by mutect2, varscan2
- MCM10 | c.1697A>T p.K566M (on ENST00000484800 / NM_182751.3; = p.K565M on NM_018518.5) | Missense Mutation (SNP) | VAF 72/395 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MDGA2 | c.1124G>C p.G375A (on ENST00000399232 / NM_001113498.2; = p.G77A on NM_182830.4) | Missense Mutation (SNP) | VAF 33/303 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED13L | c.3580G>T p.G1194C | Missense Mutation (SNP) | VAF 222/921 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MEI1 | c.3143C>T p.P1048L | Missense Mutation (SNP) | VAF 62/375 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- MKS1 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 123/741 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- MME | c.1976A>T p.Y659F | Missense Mutation (SNP) | VAF 92/340 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- MNDA | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 52/307 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- MOB3C | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MORC1 | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- MS4A7 | c.577G>C p.V193L | Missense Mutation (SNP) | VAF 51/378 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- MUC12 | c.9059G>C p.G3020A (on ENST00000379442; = p.G2877A on NM_001164462.1) | Missense Mutation (SNP) | VAF 304/4648 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); called by muse, mutect2
- MUC16 | c.34208T>C p.M11403T | Missense Mutation (SNP) | VAF 80/410 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MUC16 | c.25340A>G p.E8447G | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MUC16 | c.5380A>C p.T1794P | Missense Mutation (SNP) | VAF 49/238 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- MUC2 | c.2110G>T p.V704L | Missense Mutation (SNP) | VAF 74/327 reads (23%) | SIFT tolerated (0.34); called by muse, mutect2, varscan2
- MYF5 | c.71C>A p.P24H | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH13 | c.3516G>T p.E1172D | Missense Mutation (SNP) | VAF 96/423 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- MYH2 | c.2216G>T p.G739V | Missense Mutation (SNP) | VAF 178/832 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH3 | c.849C>G p.S283R | Missense Mutation (SNP) | VAF 152/756 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MYLK4 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 72/295 reads (24%) | called by muse, mutect2, varscan2
- MYOM2 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- MYOM2 | c.4177G>A p.V1393M | Missense Mutation (SNP) | VAF 49/511 reads (10%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- NALCN | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 23/253 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NAT1 | c.268G>T p.G90* | Nonsense Mutation (SNP) | VAF 28/336 reads (8%) | called by muse, mutect2
- NBPF15 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 134/1048 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- NCAPD2 | c.2021G>C p.G674A | Missense Mutation (SNP) | VAF 96/368 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NCKIPSD | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- NCOA6 | c.3203T>A p.M1068K | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- NDN | c.396C>G p.Y132* | Nonsense Mutation (SNP) | VAF 43/237 reads (18%) | called by muse, mutect2, varscan2
- NEFL | c.92G>T p.S31I | Missense Mutation (SNP) | VAF 38/290 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- NEFL | c.91A>T p.S31C | Missense Mutation (SNP) | VAF 39/295 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- NLRP11 | c.1706C>A p.T569K | Missense Mutation (SNP) | VAF 64/446 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NLRP13 | c.2917T>C p.C973R | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- NLRP4 | c.1396C>A p.L466I | Missense Mutation (SNP) | VAF 90/378 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.862); called by muse, varscan2
- NMD3 | c.1135G>T p.D379Y | Missense Mutation (SNP) | VAF 53/316 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- NME8 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 68/824 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2
- NPAP1 | c.1837C>A p.H613N | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- NPC1L1 | c.945G>T p.K315N | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- NRP1 | c.1271G>T p.C424F | Missense Mutation (SNP) | VAF 93/394 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NSD1 | c.6554A>T p.Q2185L | Missense Mutation (SNP) | VAF 100/281 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- NSUN7 | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 40/255 reads (16%) | called by muse, mutect2, varscan2
- NTNG1 | c.173C>A p.T58K | Missense Mutation (SNP) | VAF 32/392 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.792); called by muse, mutect2
- NUP42 | c.564G>T p.R188S | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OGFOD1 | c.334_341del p.I112Ffs*7 | Frame Shift Del (DEL) | VAF 45/349 reads (13%) | called by mutect2, pindel, varscan2
- OR14K1 | c.694C>G p.Q232E | Missense Mutation (SNP) | VAF 105/538 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- OR2A12 | c.40T>A p.L14M | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- OR2M3 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 142/654 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- OR4C6 | c.826A>G p.I276V | Missense Mutation (SNP) | VAF 53/439 reads (12%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR4K2 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 64/537 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4P4 | c.837G>T p.M279I | Missense Mutation (SNP) | VAF 53/337 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- OR4Q3 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 57/850 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- OR4S2 | c.254C>G p.A85G | Missense Mutation (SNP) | VAF 82/439 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- OR51B2 | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5AC2 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, varscan2
- OR5AC2 | c.102G>T p.L34F | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.029); called by muse, varscan2
- OR5AS1 | c.836C>A p.T279N | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- OR5B3 | c.571C>A p.H191N | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR5F1 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- OR5I1 | c.738C>A p.H246Q | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR5M1 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- OR6K2 | c.570C>A p.D190E | Missense Mutation (SNP) | VAF 85/417 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- OR7E24 | c.599C>A p.S200Y | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR7G2 | c.378G>C p.L126F | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OR8H2 | c.254A>T p.N85I | Missense Mutation (SNP) | VAF 75/388 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- OR8K3 | c.607G>C p.A203P | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- OTOG | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 57/251 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OVCH1 | c.263G>T p.C88F | Missense Mutation (SNP) | VAF 98/389 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- P2RX3 | c.283A>G p.K95E | Missense Mutation (SNP) | VAF 55/333 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- P2RY10 | c.301T>G p.F101V | Missense Mutation (SNP) | VAF 72/149 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PABPC1L | c.1240-4G>C | Splice Region (SNP) | VAF 54/87 reads (62%) | called by muse, mutect2, varscan2
- PARD3B | c.2306C>A p.P769Q (on ENST00000406610 / NM_001302769.2; = p.P707Q on NM_152526.6) | Missense Mutation (SNP) | VAF 226/404 reads (56%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH10 | c.2443C>A p.H815N | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- PCDH17 | c.2956A>T p.T986S | Missense Mutation (SNP) | VAF 110/530 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- PCDHA12 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 94/417 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB14 | c.1290G>T p.R430S | Missense Mutation (SNP) | VAF 186/594 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.513); called by muse, varscan2
- PCDHGA3 | c.1169T>C p.L390P | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- PCDHGA8 | c.1071A>T p.L357F | Missense Mutation (SNP) | VAF 139/564 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- PCNX1 | c.3080G>T p.G1027V | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCSK7 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 114/317 reads (36%) | called by muse, mutect2, varscan2
- PDXDC1 | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 93/832 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PFN4 | c.118-2A>T p.X40_splice | Splice Site (SNP) | VAF 23/220 reads (10%) | called by muse, mutect2, varscan2
- PHEX | c.1966-1G>T p.X656_splice | Splice Site (SNP) | VAF 91/245 reads (37%) | called by muse, mutect2, varscan2
- PKD1L1 | c.4860-1G>A p.X1620_splice | Splice Site (SNP) | VAF 39/364 reads (11%) | called by muse, mutect2
- PLCB3 | c.2329G>T p.D777Y | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PLCB4 | c.2182G>A p.G728R | Missense Mutation (SNP) | VAF 87/500 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCL1 | c.1288G>T p.G430W | Missense Mutation (SNP) | VAF 106/237 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCXD2 | c.22A>T p.R8W | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.721); called by muse, varscan2
- PLEKHA6 | c.647G>T p.C216F | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHN1 | c.682C>T p.Q228* (on ENST00000379409; = p.Q188* on NM_032129.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- PLIN5 | c.769G>T p.G257W | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PLOD2 | c.954G>C p.L318F | Missense Mutation (SNP) | VAF 69/300 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLSCR1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 54/278 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- PLSCR5 | c.423C>A p.N141K | Missense Mutation (SNP) | VAF 82/346 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PNLIPRP2 | c.1196C>A p.A399E (on ENST00000611850; = p.A400E on NM_005396.5) | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- PNMA2 | c.375del p.Q126Rfs*35 | Frame Shift Del (DEL) | VAF 26/99 reads (26%) | called by mutect2, pindel, varscan2
- POLD1 | c.542A>T p.E181V | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- POLR3E | c.291G>C p.M97I | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POU2F1 | c.16G>T p.E6* (on ENST00000541643 / NM_001365848.1; = p.E29* on NM_002697.4) | Nonsense Mutation (SNP) | VAF 53/278 reads (19%) | called by muse, mutect2, varscan2
- PPP4R3C | c.2078T>G p.V693G | Missense Mutation (SNP) | VAF 74/208 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PRAMEF19 | c.1025C>A p.A342D | Missense Mutation (SNP) | VAF 228/1057 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- PRDM16 | c.2512G>A p.G838R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- PRDM8 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 177/585 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PRDM9 | c.1400C>A p.T467K | Missense Mutation (SNP) | VAF 145/937 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- PRMT7 | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PRPSAP2 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PTER | c.620G>T p.R207M | Missense Mutation (SNP) | VAF 111/463 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- PTGES3 | c.320A>G p.K107R | Missense Mutation (SNP) | VAF 42/368 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTPN21 | c.2522del p.K841Rfs*4 | Frame Shift Del (DEL) | VAF 40/178 reads (22%) | called by mutect2, pindel, varscan2
- PTPRB | c.2505G>T p.L835F | Missense Mutation (SNP) | VAF 79/350 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRG | c.425G>T p.R142I | Missense Mutation (SNP) | VAF 91/309 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPRT | c.1913G>A p.R638K | Missense Mutation (SNP) | VAF 247/392 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PXDNL | c.1857G>T p.Q619H | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- RADX | c.986del p.C329Sfs*2 | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | called by mutect2, pindel, varscan2
- RAI1 | c.5152A>T p.K1718* | Nonsense Mutation (SNP) | VAF 116/537 reads (22%) | called by muse, mutect2, varscan2
- RAMP1 | c.88G>C p.A30P | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RASA3 | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 63/242 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASGEF1A | c.1232G>T p.W411L | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- RASGEF1B | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 188/576 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, varscan2
- RAVER1 | c.1632G>T p.Q544H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM47 | c.1660A>T p.T554S (on ENST00000295971 / NM_001098634.2; = p.T485S on NM_019027.4) | Missense Mutation (SNP) | VAF 86/340 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.112); called by muse, varscan2
- RET | c.1987T>G p.F663V | Missense Mutation (SNP) | VAF 133/429 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RETREG3 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 18/338 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.131); called by muse, mutect2
- RFNG | c.267+7del | Splice Region (DEL) | VAF 10/33 reads (30%) | called by mutect2, pindel
- RFT1 | c.581T>G p.V194G | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- RGS22 | c.2125C>A p.Q709K | Missense Mutation (SNP) | VAF 26/357 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- RGS7 | c.227-1G>A p.X76_splice | Splice Site (SNP) | VAF 135/789 reads (17%) | called by muse, mutect2, varscan2
- RMDN3 | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 50/230 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- RNF5 | c.86T>C p.I29T | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ROR2 | c.2127G>T p.Q709H | Missense Mutation (SNP) | VAF 109/239 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- RP1L1 | c.5287del p.A1763Qfs*35 | Frame Shift Del (DEL) | VAF 97/432 reads (22%) | called by mutect2, pindel, varscan2
- RPIA | c.402G>T p.Q134H | Missense Mutation (SNP) | VAF 74/892 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RPL10L | c.456G>T p.L152F | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- RPL22L1 | c.102+1del p.X34_splice | Splice Site (DEL) | VAF 50/403 reads (12%) | called by mutect2, pindel, varscan2
- RSRC1 | c.802G>C p.G268R | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RTL1 | c.101A>T p.E34V | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RXFP3 | c.759C>A p.D253E | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- RYR2 | c.1959C>A p.S653R | Missense Mutation (SNP) | VAF 125/419 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- RYR2 | c.1960A>G p.S654G | Missense Mutation (SNP) | VAF 121/409 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RYR3 | c.9518G>T p.G3173V (on ENST00000389232; = p.G3174V on NM_001036.6) | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SAMD9L | c.1578G>T p.R526S | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SART3 | c.2744T>A p.M915K (on ENST00000228284; = p.M897K on NM_014706.4) | Missense Mutation (SNP) | VAF 57/333 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SCIN | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 36/388 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SCLT1 | c.1832G>T p.S611I | Missense Mutation (SNP) | VAF 55/227 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- SCN10A | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 63/295 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCN3B | c.119C>G p.P40R | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- SDK2 | c.4256T>C p.L1419P | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- SERPINB5 | c.387A>T p.K129N | Missense Mutation (SNP) | VAF 44/326 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- SERPINB6 | c.370-3T>A | Splice Region (SNP) | VAF 68/712 reads (10%) | called by muse, mutect2
- SETBP1 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 269/1313 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SGCB | c.862T>C p.C288R | Missense Mutation (SNP) | VAF 121/639 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SGCD | c.485G>C p.R162T (on ENST00000435422 / NM_001128209.2; = p.R163T on NM_000337.5) | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.684); called by muse, mutect2
- SH3TC1 | c.3470del p.K1157Sfs*23 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | called by pindel, varscan2
- SHANK1 | c.1606G>T p.G536C | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- SHISA3 | c.179G>T p.C60F | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SHISA3 | c.677del p.P226Hfs*19 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel
- SI | c.2675T>A p.V892E | Missense Mutation (SNP) | VAF 101/241 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- SLA2 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 134/219 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- SLC12A1 | c.2026C>A p.H676N | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC12A2 | c.3137A>T p.K1046M | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SLC22A31 | c.233_237delinsATCCA p.G78D | Missense Mutation (ONP) | VAF 7/57 reads (12%) | called by mutect2*, pindel
- SLC22A6 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- SLC25A6 | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLC28A3 | c.905T>C p.L302P | Missense Mutation (SNP) | VAF 134/366 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC35F1 | c.121T>C p.S41P | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SLC44A5 | c.1338G>T p.K446N | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC44A5 | c.987G>A p.M329I | Missense Mutation (SNP) | VAF 51/407 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SLC5A7 | c.1438A>G p.K480E | Missense Mutation (SNP) | VAF 87/217 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- SLC6A17 | c.1206C>A p.Y402* | Nonsense Mutation (SNP) | VAF 63/299 reads (21%) | called by muse, mutect2, varscan2
- SLCO1C1 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 92/479 reads (19%) | called by muse, varscan2
- SMAD5 | c.383A>T p.Y128F | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMR3A | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 102/567 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- SOX5 | c.1697G>C p.W566S | Missense Mutation (SNP) | VAF 60/264 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SP140 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 49/152 reads (32%) | called by muse, mutect2, varscan2
- SPCS2 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- SPEF2 | c.3886G>C p.G1296R | Missense Mutation (SNP) | VAF 154/513 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SPEN | c.6048G>T p.E2016D | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPRY3 | c.150G>T p.K50N | Missense Mutation (SNP) | VAF 101/667 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); called by muse, varscan2
- SPTA1 | c.4917G>T p.L1639F | Missense Mutation (SNP) | VAF 163/740 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SRCAP | c.7832T>A p.L2611* | Nonsense Mutation (SNP) | VAF 69/267 reads (26%) | called by muse, mutect2, varscan2
- SST | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 160/1229 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SSTR4 | c.249C>G p.N83K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- ST6GALNAC3 | c.24G>T p.K8N | Missense Mutation (SNP) | VAF 26/128 reads (20%) | PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- ST6GALNAC3 | c.584A>T p.Y195F | Missense Mutation (SNP) | VAF 30/200 reads (15%) | PolyPhen benign (0.142); called by muse, varscan2
- STK38L | c.895G>A p.G299S | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3161A>T p.D1054V | Missense Mutation (SNP) | VAF 45/454 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- STUB1 | c.275A>G p.Q92R | Missense Mutation (SNP) | VAF 58/270 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SUPT20HL2 | c.1409G>T p.S470I | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- SUPT3H | c.763G>T p.V255L (on ENST00000371460 / NM_181356.3; = p.V244L on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/821 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2
- TAF15 | c.490C>T p.R164C (on ENST00000605844 / NM_139215.3; = p.R161C on NM_003487.4) | Missense Mutation (SNP) | VAF 40/678 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- TAF3 | c.838G>T p.G280* | Nonsense Mutation (SNP) | VAF 100/383 reads (26%) | called by muse, mutect2, varscan2
- TAS2R41 | c.923A>T p.*308Lext*? | Nonstop Mutation (SNP) | VAF 44/77 reads (57%) | called by muse, mutect2, varscan2
- TDRD3 | c.1114G>T p.E372* | Nonsense Mutation (SNP) | VAF 24/156 reads (15%) | called by muse, mutect2, varscan2
- TDRD9 | c.295C>A p.R99S | Missense Mutation (SNP) | VAF 77/453 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEKT2 | c.468C>G p.S156R | Missense Mutation (SNP) | VAF 133/487 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TEKT4 | c.1199del p.L400Rfs*8 | Frame Shift Del (DEL) | VAF 59/592 reads (10%) | called by mutect2, varscan2
- TENM3 | c.2082del p.T695Rfs*81 | Frame Shift Del (DEL) | VAF 72/298 reads (24%) | called by pindel, varscan2
- TEP1 | c.181A>T p.M61L | Missense Mutation (SNP) | VAF 96/370 reads (26%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- TG | c.1519G>T p.A507S | Missense Mutation (SNP) | VAF 173/736 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- THEGL | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 74/393 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- THSD7A | c.1562G>T p.W521L | Missense Mutation (SNP) | VAF 39/360 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIA1 | c.1141del p.A381Qfs*8 (on ENST00000433529 / NM_001351511.1; = p.A370Qfs*8 on NM_022037.4 and 9 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 37/363 reads (10%) | called by mutect2, varscan2
- TIPARP | c.1330A>C p.T444P | Missense Mutation (SNP) | VAF 187/975 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TLN2 | c.3180G>T p.Q1060H | Missense Mutation (SNP) | VAF 45/307 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- TMEM132D | c.1742C>A p.T581K | Missense Mutation (SNP) | VAF 76/222 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM168 | c.1237G>T p.G413* | Nonsense Mutation (SNP) | VAF 39/376 reads (10%) | called by muse, mutect2, varscan2
- TMEM171 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- TMEM245 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TMEM71 | c.927G>T p.K309N | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- TNRC18 | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNS2 | c.186C>G p.V62= (on ENST00000314250 / NM_170754.4; = p.V72= on NM_015319.2) | Splice Region (SNP) | VAF 50/213 reads (23%) | called by muse, mutect2, varscan2
- TOPAZ1 | c.3521T>A p.L1174* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- TOX2 | c.1085A>G p.K362R (on ENST00000358131 / NM_001098798.2; = p.K338R on NM_032883.3) | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TOX3 | c.907-1G>C p.X303_splice | Splice Site (SNP) | VAF 77/268 reads (29%) | called by muse, mutect2, varscan2
- TP53BP2 | c.2338T>A p.S780T (on ENST00000343537 / NM_001031685.3; = p.S651T on NM_005426.2) | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRAV6 | c.200A>T p.Y67F | Missense Mutation (SNP) | VAF 75/324 reads (23%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- TRBV29-1 | c.324C>A p.C108* | Nonsense Mutation (SNP) | VAF 66/160 reads (41%) | called by muse, varscan2
- TRHDE | c.3034G>C p.D1012H | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRIM49B | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- TRIM64 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 71/412 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TRIM64C | c.389G>T p.W130L | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- TRPM2 | c.2738T>A p.I913N | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- TSPAN15 | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- TSPAN8 | c.350T>G p.V117G | Missense Mutation (SNP) | VAF 62/347 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- TTLL7 | c.505G>T p.G169W | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTLL8 | c.1182C>A p.Y394* | Nonsense Mutation (SNP) | VAF 108/454 reads (24%) | called by muse, mutect2, varscan2
- TTN | c.96385C>G p.L32129V (on ENST00000591111; = p.L24705V on NM_003319.4) | Missense Mutation (SNP) | VAF 718/1366 reads (53%) | PolyPhen benign (0.076); called by muse, mutect2, varscan2
- TTN | c.45394G>T p.E15132* (on ENST00000591111; = p.E7708* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 279/567 reads (49%) | called by muse, mutect2, varscan2
- TTN | c.44311G>T p.A14771S (on ENST00000591111; = p.A7347S on NM_003319.4) | Missense Mutation (SNP) | VAF 551/1146 reads (48%) | PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- TTN | c.37710A>G p.I12570M (on ENST00000591111; = p.I5146M on NM_003319.4) | Missense Mutation (SNP) | VAF 293/667 reads (44%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.36454del p.V12152Sfs*8 (on ENST00000591111; = p.V4728Sfs*8 on NM_003319.4) | Frame Shift Del (DEL) | VAF 43/88 reads (49%) | called by mutect2, pindel, varscan2
- TUBA3C | c.803C>A p.P268H | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TUBB2B | c.758T>A p.L253Q | Missense Mutation (SNP) | VAF 90/540 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.644); called by muse, varscan2
- UBE4A | c.1442A>G p.H481R (on ENST00000252108 / NM_001204077.2; = p.H488R on NM_004788.4) | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- UNC13C | c.5251G>T p.E1751* | Nonsense Mutation (SNP) | VAF 21/291 reads (7%) | called by muse, mutect2
- UNC5D | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- UNC80 | c.4645C>A p.L1549M | Missense Mutation (SNP) | VAF 58/308 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.033); called by mutect2, varscan2
- UPF1 | c.532dup p.E178Gfs*25 | Frame Shift Ins (INS) | VAF 56/319 reads (18%) | called by mutect2, pindel, varscan2
- USH2A | c.4391C>A p.A1464E | Missense Mutation (SNP) | VAF 136/609 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- USP15 | c.1769del p.G590Vfs*23 (on ENST00000280377 / NM_001351159.2; = p.G561Vfs*23 on NM_006313.3 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 25/220 reads (11%) | called by mutect2, pindel, varscan2
- USP31 | c.3734G>T p.G1245V | Missense Mutation (SNP) | VAF 73/365 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- USP33 | c.2590G>C p.G864R | Missense Mutation (SNP) | VAF 39/297 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- VASP | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- VSX1 | c.560A>T p.H187L | Missense Mutation (SNP) | VAF 128/467 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- WNT3 | c.204C>A p.S68R | Missense Mutation (SNP) | VAF 48/257 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ZBED4 | c.2980T>A p.S994T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ZC3H14 | c.692G>T p.R231M | Missense Mutation (SNP) | VAF 92/911 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZC3H14 | c.693G>T p.R231S | Missense Mutation (SNP) | VAF 88/913 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2
357 further variants in this file (30 protein-altering or splice-affecting, 194 silent, 133 other) are not listed here.
